Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3502, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3502-01A (Primary Tumor).

*** Diagnosis / Diagnoses: ***

Resected cross-section of the colon with tumor-free resection margins, under inclusion of a tubular adenoma with mild dysplasia (synonym: low-grade intra-epithelial neoplasia) and a tubulovillous adenoma with focal severe dysplasia (synonym: high-grade intra-epithelial neoplasia) and with a well to moderately differentiated colorectal adenocarcinoma (G1 to 2) with infiltration of the lamina muscularis propria and without regional lymph node metastases (pT2 pN0 0/31) on the base of a further tubulovillous adenoma with severe dysplasia.

Final preliminary results

Source: NCI Genomic Data Commons file 2dc19d08-c870-4216-a281-f0f1ecf419ba (TCGA-AA-3502.DD52C1F9-7093-45B8-9C5A-2DEDB13E766F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).